Somatic mutation profile of tumor specimen TCGA-IB-AAUU-01A (aliquot TCGA-IB-AAUU-01A-11D-A377-08) from TCGA case TCGA-IB-AAUU, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 35.9 years (13,127 days).
Specimen TCGA-IB-AAUU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 435adf33-0526-40c4-9f32-dde9b820025a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-AAUU-10A (Blood Derived Normal), aliquot TCGA-IB-AAUU-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e5df381c-659b-40b7-8de3-1181cc942012

The open-access MAF lists 45 somatic variants for this specimen: 33 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, Silent 10, Frame Shift Ins 3, Splice Site 1, 3'Flank 1, 5'UTR 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 80/342 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCB5 | c.3559G>A p.D1187N (on ENST00000404938 / NM_001163941.2; = p.D742N on NM_178559.6) | Missense Mutation (SNP) | VAF 66/486 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); catalogued as rs759087816, COSV51703971; called by muse, mutect2, varscan2
- ADAM2 | c.598G>T p.V200F | Missense Mutation (SNP) | VAF 48/621 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV99697696; called by muse, mutect2
- BACH1 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 113/667 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as COSV99728534; called by muse, mutect2, varscan2
- CHMP4C | c.632G>A p.R211Q | Missense Mutation (SNP) | VAF 61/331 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.019); catalogued as rs562691343, COSV51927177, COSV99794247; called by muse, mutect2, varscan2
- CHRNA7 | c.1135G>A p.A379T | Missense Mutation (SNP) | VAF 61/345 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs573369306, COSV60970070; called by muse, mutect2, varscan2
- CLSTN2 | c.1078G>A p.G360S | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771528135, COSV101515851; called by muse, mutect2, varscan2
- DGKI | c.1698+2T>G p.X566_splice | Splice Site (SNP) | VAF 23/266 reads (9%) | catalogued as COSV99936297; called by muse, mutect2
- DHX8 | c.748C>T p.R250W | Missense Mutation (SNP) | VAF 117/462 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs146727331; called by muse, mutect2, varscan2
- DIP2A | c.3627C>T p.C1209= | Splice Region (SNP) | VAF 10/95 reads (11%) | catalogued as COSV100596202; called by muse, mutect2
- ERCC2 | c.806C>T p.T269M | Missense Mutation (SNP) | VAF 47/344 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as rs1161399233, COSV55543317; called by muse, mutect2, varscan2
- FAM47C | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 151/291 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.237); catalogued as COSV100792847; called by muse, mutect2, varscan2
- GLMN | c.288A>T p.L96F | Missense Mutation (SNP) | VAF 53/326 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); catalogued as rs773138735, COSV100950133; called by muse, mutect2, varscan2
- GRK7 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 43/343 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs778754729, COSV53823114, COSV99380106; called by muse, mutect2, varscan2
- HECW2 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 104/886 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as rs1284621782, COSV53673584; called by muse, mutect2, varscan2
- HYDIN | c.10618G>A p.A3540T | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs774036864, COSV66871097; called by muse, mutect2, varscan2
- LHX3 | c.481C>T p.R161C (on ENST00000371748 / NM_178138.6; = p.R166C on NM_014564.5) | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1192983856, COSV65581534; called by muse, mutect2
- LRRC55 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 57/459 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs143027441, COSV73006819; called by muse, mutect2, varscan2
- MROH2B | c.235G>T p.V79F | Missense Mutation (SNP) | VAF 30/320 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV101270847; called by muse, mutect2
- MUS81 | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100337343; called by muse, mutect2, varscan2
- MYO16 | c.3878G>A p.R1293Q | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779167722, COSV62748253; called by muse, mutect2, varscan2
- PDCD11 | c.2516C>T p.T839M | Missense Mutation (SNP) | VAF 48/348 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.443); catalogued as rs142899352; called by muse, mutect2, varscan2
- SLAIN2 | c.596C>G p.P199R | Missense Mutation (SNP) | VAF 137/494 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV99971796; called by muse, mutect2, varscan2
- SLC12A3 | c.2147A>G p.D716G | Missense Mutation (SNP) | VAF 29/330 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV99344566; called by muse, mutect2
- TBC1D1 | c.1131G>T p.Q377H | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV99791844; called by muse, mutect2
- YLPM1 | c.4718G>A p.R1573Q | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1391928473, COSV99460820; called by muse, mutect2, varscan2
- ZFP42 | c.679G>A p.V227I | Missense Mutation (SNP) | VAF 58/361 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs200711766, COSV58816789; called by muse, mutect2, varscan2
- ZMAT4 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 270/3821 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV52692263, COSV99910802; called by muse, mutect2
- ZNF700 | c.1892C>T p.S631F | Missense Mutation (SNP) | VAF 78/444 reads (18%) | SIFT tolerated (0.69); PolyPhen probably damaging (0.93); catalogued as COSV54311069; called by muse, mutect2, varscan2
- MUC5AC | c.744dup p.Q249Sfs*6 | Frame Shift Ins (INS) | VAF 25/135 reads (19%) | called by mutect2, varscan2
- PCDHB5 | c.466dup p.I156Nfs*6 | Frame Shift Ins (INS) | VAF 56/430 reads (13%) | called by mutect2, pindel, varscan2
- TP53 | c.366dup p.T123Dfs*26 | Frame Shift Ins (INS) | VAF 48/272 reads (18%) | called by mutect2, pindel, varscan2
- ZNF566 | c.283del p.Y95Mfs*3 | Frame Shift Del (DEL) | VAF 98/832 reads (12%) | called by mutect2, varscan2
- CPVL | c.498C>T p.H166= | Silent (SNP) | VAF 38/284 reads (13%) | catalogued as rs761586784, COSV99605617; called by muse, mutect2, varscan2
- HMG20B | c.162C>T p.R54= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs760416634, COSV99503025; called by muse, varscan2
- LTB4R2 | c.396C>T p.C132= (on ENST00000528054; = p.C101= on NM_019839.5) | Silent (SNP) | VAF 41/330 reads (12%) | catalogued as rs766430819, COSV99351029; called by muse, mutect2
- PDCD1LG2 | c.345G>A p.L115= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs1465011039, COSV101173111; called by muse, mutect2, varscan2
- PREX1 | c.3321C>T p.I1107= | Silent (SNP) | VAF 82/296 reads (28%) | catalogued as COSV100906636; called by muse, mutect2
- PRSS55 | c.28C>T p.L10= | Silent (SNP) | VAF 108/290 reads (37%) | catalogued as COSV100153856; called by muse, mutect2, varscan2
- SLC18A3 | c.1017G>T p.V339= | Silent (SNP) | VAF 75/655 reads (11%) | catalogued as rs1185226293, COSV100340650; called by muse, mutect2, varscan2
- STIP1 | c.1515C>T p.R505= | Silent (SNP) | VAF 59/208 reads (28%) | catalogued as COSV99656734; called by muse, mutect2, varscan2
- TOX4 | c.1398T>C p.P466= | Silent (SNP) | VAF 64/682 reads (9%) | catalogued as COSV99398482; called by muse, mutect2
- TTN | c.92451G>A p.T30817= (on ENST00000591111; = p.T23393= on NM_003319.4) | Silent (SNP) | VAF 52/191 reads (27%) | catalogued as rs878887772, COSV100623173; called by muse, mutect2, varscan2
- CHST8 | c.-2G>A | 5'UTR (SNP) | VAF 54/526 reads (10%) | catalogued as rs572454321, COSV52861829; called by muse, mutect2, varscan2
- L2HGDH | chr14:50237705 G>A | 3'Flank (SNP) | VAF 16/139 reads (12%) | catalogued as rs756741363, COSV99910470; called by muse, mutect2
